Surgical pathology report (de-identified scan), TCGA case TCGA-JY-A6FG, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University Health Network, specimen TCGA-JY-A6FG-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Service:

Visit #:

Accession #:

Collected:

Received:

Gender: M

Location:

Reported:

Ordering MD:

Copy To:

Facility:

Specimen(s) Received

1. Stom-Resection: stomach and distal esophagus *stitch marks proximal margin
2. Lymph node: common hepatic nodes
3. Lymph node: common hepatic nodes

Diagnosis

1. Stomach and distal esophagus, total gastrectomy and distal esophagectomy:
- squamous cell carcinoma, well to moderately differentiated, involving GE junction and proximal stomach with approximately 1.5 cm extension into distal esophagus – see synoptic data and comment
- resection margins: negative for carcinoma
- metastatic squamous cell carcinoma in 5/18 lymph nodes (total lymph node count includes specimens #2 and #3)
2. Lymph node: common hepatic nodes
- lymph nodes x2: negative for carcinoma
3. Lymph node: common hepatic nodes
- lymph nodes x3: negative for carcinoma.

ICD-O-3
Carcinoma, squamous cell NOS
8070/3
Site Esophagus, distal third
906110/13 path
Gastroesophageal junction
C16.0

Comment

1. The tumor is centered in the proximal stomach where it involves the entire gastric circumference. The tumor involves the GE junction and approximately 1.0 cm of the distal esophagus. On the esophageal side, the tumor focally invades adventitia and is 0.2 cm from the adventitial surface at the closest point. On the gastric side, the tumor extends into perigastric fat and is approximately 1.2 cm from the radial margin. The tumor is a well to moderately differentiated squamous cell carcinoma and given the presence of GEJ and distal esophageal involvement, is staged as an esophageal carcinoma. There are a total of 18 lymph nodes identified including specimens #2 and #3, 5 of which contain metastatic squamous cell carcinoma.

Synoptic Data

Specimen Type:	Esophagogastrectomy
Tumor Site:	distal esophagus
Tumor Size:	Greatest dimension: 17.0 cm Additional dimensions: 6.3 x 2.2 cm
Histologic Type:	Squamous cell carcinoma
Histologic Grade:	G2: Moderately differentiated

[page 2 of 3]
Surgical Pathology Consultation Report

Pathologic Staging (pTNM): pT3: Tumor invades adventitia
pN1b: 4 to 7 nodes involved
Number of lymph nodes examined: 18
Number of lymph nodes involved: 5
Margins: Proximal margin-Uninvolved by invasive carcinoma
Distal margin-Uninvolved by invasive carcinoma
Circumferential (Adventitial) margin-Uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 2.0 mm
Margin: adventitial
Venous (Large Vessel) Invasion (V): Absent
Lymphatic (Small Vessel) Invasion (L): Present

*Pathologic Staging is based on AJCC/UICC TNM, 6th Edition

Electronically verified by:

Gross Description

1. STOMACH RESECTION FOR TUMOR
(INCLUDES GE JUNCTION TUMORS)

GROSS EXAMINATION

RESECTION SPECIMEN: Distal esophagectomy and Total gastrectomy

FIXATION: Fixed

DIMENSIONS:

Length along lesser curvature: 17.0 cm
Length along greater curvature: 33.0 cm
Circumference of distal gastric margin: 5.0 cm
Length of tubular esophagus: 2.0 cm
Circumference of proximal (esophageal) margin: 3.5 cm

TUMOR:

LOCATION:

- GEJ, proximal stomach and distal esophagus; grossly ~ 1.5 cm into distal esophagus and 4.8 cm into the proximal stomach

- CONFIGURATION: exophytic, ulcerative

- DIMENSIONS: Diameters 6.3 x 17.0 cm
Depth 2.2 cm

- DESCRIPTIVE CHARACTERISTICS: Tan-brown in color, solid in consistency. With centrally ulcerated area and irregular heaped up edges

- PERFORATION: no

- DISTANCE FROM MARGINS:

- PROXIMAL: less than 1.0 cm
- DISTAL: 9.5 cm

[page 3 of 3]
Surgical Pathology Consultation Report

- RADIAL: 1.2 cm (non-peritonealized soft tissue margin closest to deepest tumor penetration)

ESTIMATED DEPTH OF INVASION : adventitia of esophagus and perigastric fat

LESIONS IN NONCANCEROUS STOMACH: None

LYMPH NODES: Multiple perigastric lymph nodes along the greater and lesser curvatures ranging in size from 0.7 to 2.5-cm.

Representative sections are submitted as follows:

1A-1B- frozen section blocks resubmitted

1C-distal gastric resection margin en face

1D- medial resection margin perpendicular sections

1E-1H-tumor at the GE Junction and distal esophagus

1I-1R-tumor at the proximal stomach showing it to deepest invasion

1S-uninvolved distal stomach

1T-1U-one lymph node each block bisected.

1V-1W-one lymph node serially sectioned

1X-one lymph node bisected

1Y-one lymph node bisected

1Z-5 lymph nodes

1AA-3 lymph nodes.

Four pieces of tumor/normal were taken for tissue bank.

2. The specimen container is labeled with the patient's name and as "Lymph Node: Common hepatic nodes consists of two fragments tissue measuring 1.8 x 1.0 x 0.6 and in other and 4.2 x 3.1 x 0.3-cm received fresh, This is examined at intraoperative consultation by frozen section performed on part of the specimen. On the bigger piece of tissue there is a nodule identified measuring 1.1 x 1.0 x 0.2 cm. The specimen is submitted in toto as follows:

2A-2B- frozen section blocks resubmitted.

2C-remainder of fatty tissue.

3. The specimen container is labeled with the patient's name and as "Lymph Node: Common hepatic nodes consists of a piece of fatty tissue measuring 2.0 x 1.7 x 0.6 and two received in 10% buffered formalin

3A specimen is bisected and submitted in toto. in

Quick Section Diagnosis

1. Stomach and distal esophagus (proximal esophageal margin en face):

- Tumour grossly > 1.0 cm away from margin.

- En face margin is negative for malignancy.

2. Common hepatic nodes:

- Two lymph nodes found, negative for malignancy (0/2).

Reviewed (initials):	5/23/13	

Source: NCI Genomic Data Commons file 41c7aaf5-bc62-48fc-bba5-c718539f916d (TCGA-JY-A6FG.C69267B7-ED3A-46CA-AC04-C6B110F5C556.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).